Somatic mutation profile of tumor specimen TCGA-61-1736-01B (aliquot TCGA-61-1736-01B-01W-0722-08) from TCGA case TCGA-61-1736, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 45.5 years (16,613 days).
Specimen TCGA-61-1736-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 562d81c3-0d46-48e8-91ac-274fb7135cd4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1736-11A (Solid Tissue Normal), aliquot TCGA-61-1736-11A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80b17dec-2714-439b-9fbe-44930474fdae

The open-access MAF lists 42 somatic variants for this specimen: 31 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 9, Splice Site 2, Nonsense Mutation 2, RNA 1, Frame Shift Ins 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>C p.G245R | Missense Mutation (SNP) | VAF 157/288 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AGBL4 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs200395475, COSV65731068; called by muse, mutect2, varscan2
- ARHGEF40 | c.2326C>A p.H776N | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV53878566; called by muse, mutect2, varscan2
- COL4A1 | c.2271G>C p.K757N | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65422268; called by muse, mutect2, varscan2
- EXOSC9 | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 16/360 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99696718; called by muse, mutect2
- GOLGA4 | c.6416G>A p.R2139H | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs371358582; called by muse, mutect2, varscan2
- GTF2F2 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV61242690; called by muse, mutect2
- HERC2 | c.10615A>T p.S3539C | Missense Mutation (SNP) | VAF 78/120 reads (65%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV55310999; called by muse, varscan2
- LETM1 | c.432dup p.A145Rfs*61 | Frame Shift Ins (INS) | VAF 8/56 reads (14%) | catalogued as rs745839823; called by mutect2, varscan2
- MMP16 | c.1699A>G p.I567V | Missense Mutation (SNP) | VAF 180/377 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV54153248; called by muse, mutect2, varscan2
- NADSYN1 | c.1648T>A p.F550I | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59810616; called by muse, mutect2, varscan2
- NEURL1 | c.1280C>T p.S427L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63913770; called by muse, mutect2, varscan2
- NNMT | c.415C>A p.L139M | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100248795; called by muse, mutect2
- OR51T1 | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 70/872 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1227457341, COSV59024019, COSV59028662; called by muse, mutect2
- PCDHB7 | c.626G>A p.S209N | Missense Mutation (SNP) | VAF 56/94 reads (60%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.022); catalogued as rs868986357, COSV50755744; called by muse, mutect2, varscan2
- RFX4 | c.681C>A p.F227L (on ENST00000392842 / NM_213594.3; = p.F133L on NM_032491.6) | Missense Mutation (SNP) | VAF 13/388 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.348); catalogued as COSV57581187, COSV99985327; called by muse, mutect2
- RGS3 | c.2455C>A p.P819T (on ENST00000350696 / NM_001282923.2; = p.P538T on NM_130795.4) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.081); catalogued as COSV100636553; called by muse, mutect2
- SLC25A29 | c.162+1G>T p.X54_splice | Splice Site (SNP) | VAF 6/9 reads (67%) | catalogued as COSV63650395; called by muse, mutect2, varscan2
- SLC6A14 | c.1075G>T p.V359L | Missense Mutation (SNP) | VAF 169/343 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.323); catalogued as COSV64146267; called by muse, mutect2, varscan2
- SOX5 | c.1403A>C p.E468A | Missense Mutation (SNP) | VAF 158/428 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58620642; called by muse, mutect2, varscan2
- TBX3 | c.946C>G p.Q316E (on ENST00000257566 / NM_016569.4; = p.Q296E on NM_005996.4) | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV57469641; called by muse, mutect2, varscan2
- TENM1 | c.1364C>A p.T455N | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64426271; called by muse, mutect2, varscan2
- UAP1 | c.461A>G p.Y154C | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs764252034, COSV54849331; called by muse, mutect2, varscan2
- USP26 | c.1463G>T p.G488V | Missense Mutation (SNP) | VAF 78/640 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.405); catalogued as COSV100896535; called by mutect2, varscan2
- WDR47 | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.417); catalogued as COSV100728225; called by muse, mutect2, varscan2
- ZNF236 | c.5334C>A p.Y1778* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as COSV53483061, COSV53483402; called by muse, mutect2, varscan2
- ZYG11B | c.1669A>T p.I557F | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs1297431552, COSV53750520; called by muse, mutect2
- FRMPD3 | c.238_239insGGAGGCTGAGGTGAGAGGATCACT p.V80delinsGRLR* | Nonsense Mutation (INS) | VAF 194/650 reads (30%) | called by mutect2, varscan2*
- IGHV1-3 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- SSTR1 | c.888del p.F296Lfs*9 | Frame Shift Del (DEL) | VAF 130/227 reads (57%) | called by mutect2, pindel, varscan2
- ZC3H14 | c.432-1G>T p.X144_splice | Splice Site (SNP) | VAF 22/145 reads (15%) | called by mutect2, varscan2
- ACSM4 | c.183G>A p.Q61= | Silent (SNP) | VAF 94/247 reads (38%) | catalogued as COSV68066944; called by muse, mutect2, varscan2
- CREB3L2 | c.1227G>A p.L409= | Silent (SNP) | VAF 43/227 reads (19%) | catalogued as COSV57792607; called by muse, mutect2, varscan2
- KIF18A | c.2457C>T p.S819= | Silent (SNP) | VAF 24/193 reads (12%) | catalogued as COSV54181522; called by muse, mutect2, varscan2
- MOV10L1 | c.1410G>A p.A470= | Silent (SNP) | VAF 19/20 reads (95%) | catalogued as rs778485550, COSV53167989; called by muse, varscan2
- PATJ | c.103T>C p.L35= | Silent (SNP) | VAF 123/254 reads (48%) | catalogued as COSV57156707; called by muse, mutect2, varscan2
- PCDHA3 | c.1848C>T p.G616= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV63539414; called by muse, mutect2, varscan2
- PDCD4 | c.228G>T p.S76= | Silent (SNP) | VAF 43/116 reads (37%) | catalogued as rs372715017, COSV54522061; called by muse, mutect2, varscan2
- PDP2 | c.969G>A p.E323= | Silent (SNP) | VAF 38/63 reads (60%) | catalogued as COSV61240165; called by muse, mutect2, varscan2
- WRN | c.2064C>A p.G688= | Silent (SNP) | VAF 13/289 reads (4%) | catalogued as COSV99988230; called by muse, mutect2
- F9 | c.*2G>A | 3'UTR (SNP) | VAF 19/56 reads (34%) | catalogued as COSV99496303; called by muse, mutect2, varscan2
- TP73-AS1 | n.1143C>T | RNA (SNP) | VAF 4/9 reads (44%) | catalogued as rs541058441; called by muse, mutect2, varscan2
